Somatic mutation profile of tumor specimen TCGA-P5-A5EX-01A (aliquot TCGA-P5-A5EX-01A-12D-A289-08) from TCGA case TCGA-P5-A5EX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.3 years (15,091 days).
Specimen TCGA-P5-A5EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a5a398a-7ccb-4a34-8b23-05b250c31341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EX-10A (Blood Derived Normal), aliquot TCGA-P5-A5EX-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8c56c3e-e54d-4608-b130-2e4a06752b7f

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BARX1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs1313975275, COSV54159334; called by muse, mutect2, varscan2
- CLDN11 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.041); catalogued as rs1409189641, COSV50355070; called by muse, mutect2, varscan2
- COA1 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV56242591; called by muse, mutect2, varscan2
- CROT | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV58975267; called by muse, mutect2, varscan2
- DCHS1 | c.3973G>A p.A1325T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1454887716; called by mutect2, varscan2
- FBXL3 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.037); catalogued as rs1462227471, COSV62918989; called by muse, mutect2, varscan2
- FOXP2 | c.1263A>T p.K421N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV63488991; called by muse, mutect2, varscan2
- KEL | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 62/205 reads (30%) | catalogued as rs565926203, CM151483, COSV62336100; called by muse, mutect2, varscan2
- KIF4A | c.2303T>G p.L768R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63285138; called by muse, mutect2, varscan2
- MAGEB1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs747784071, COSV100975132, COSV66776023; called by muse, mutect2, varscan2
- MPRIP | c.1058dup p.A354Sfs*43 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | catalogued as rs778181735; called by mutect2, varscan2
- NMBR | c.778A>T p.T260S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV57802074; called by muse, mutect2, varscan2
- NUP98 | c.5392A>G p.M1798V (on ENST00000359171 / NM_001365126.1; = p.M1781V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs746840477, COSV51709812; called by muse, mutect2
- PRX | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs780212559, COSV52530674; called by muse, mutect2
- TENM1 | c.5891C>G p.T1964R | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64436220; called by muse, mutect2, varscan2
- TSPOAP1 | c.3035A>G p.N1012S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52112107; called by muse, mutect2, varscan2
- VIRMA | c.733_735del p.Q245del | In Frame Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1195989349; called by pindel, varscan2
- WIPI2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs771996943, COSV56586762; called by muse, mutect2, varscan2
- UBR5 | c.4127G>A p.G1376D | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BOD1L1 | c.5439C>T p.S1813= | Silent (SNP) | VAF 24/209 reads (11%) | catalogued as rs753136155, COSV50023651; called by muse, mutect2, varscan2
- BRWD3 | c.3891T>C p.S1297= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV64750414; called by muse, mutect2, varscan2
- MINAR1 | c.750C>T p.V250= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV59584331; called by muse, mutect2, varscan2
- SOGA1 | c.1113C>A p.A371= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs373774469, COSV52923310; called by muse, mutect2, varscan2
- TTN | c.90753T>C p.S30251= (on ENST00000591111; = p.S22827= on NM_003319.4) | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV60169398; called by muse, mutect2, varscan2
- ZC3H6 | c.3171A>G p.S1057= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV59669117; called by muse, mutect2, varscan2
- ATP5F1B | c.310+78dup | Intron (INS) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
